Somatic mutation profile of tumor specimen HCM-CSHL-0178-C25-01A (aliquot HCM-CSHL-0178-C25-01A-21D-A78T-36) from HCMI case HCM-CSHL-0178-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 71.1 years (25,954 days).
Specimen HCM-CSHL-0178-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53bcfa00-23b1-457e-b007-4ae24d0a8a29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0178-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0178-C25-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce1cb8f1-9f1b-4e8d-a47b-ea665ef4a574

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Nonsense Mutation 4, 3'UTR 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 194/428 reads (45%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 78/300 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 96/212 reads (45%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC136 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs770281978; called by muse, mutect2, varscan2
- CENPE | c.2608T>C p.Y870H | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99477181; called by muse, mutect2, varscan2
- COL7A1 | c.2477_2478del p.T826Rfs*39 | Frame Shift Del (DEL) | VAF 108/424 reads (25%) | catalogued as rs1559427174; called by pindel, varscan2
- CTBP1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 16/479 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs1390818109, COSV99337427; called by muse, mutect2
- FLT4 | c.4060C>T p.R1354C | Missense Mutation (SNP) | VAF 122/388 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.17); catalogued as rs761089407, COSV56098461; called by muse, mutect2, varscan2
- GRIK3 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs771026654, COSV66135816; called by muse, mutect2, varscan2
- KCTD19 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 125/383 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs747458440; called by muse, mutect2, varscan2
- NBEA | c.8159G>T p.W2720L | Missense Mutation (SNP) | VAF 99/389 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV59829009; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2
- PGR | c.1039T>C p.C347R | Missense Mutation (SNP) | VAF 115/425 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV54800152; called by muse, mutect2, varscan2
- PKHD1L1 | c.7958C>T p.T2653I | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1433716372; called by muse, mutect2, varscan2
- PLXND1 | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 144/491 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs767303855, COSV60710688; called by muse, mutect2, varscan2
- POM121L12 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 158/499 reads (32%) | catalogued as rs1418866673, COSV68694385; called by muse, mutect2, varscan2
- SHE | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 145/492 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs781170865, COSV59072167; called by muse, mutect2, varscan2
- TRIO | c.7037G>A p.R2346Q | Missense Mutation (SNP) | VAF 609/909 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as rs761855758; called by muse, mutect2, varscan2
- ZIM3 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 129/365 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs774474471, COSV54140013; called by muse, mutect2, varscan2
- CAPN15 | c.2953C>T p.L985F | Missense Mutation (SNP) | VAF 156/449 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLIP4 | c.561T>G p.F187L | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); called by muse, varscan2
- CPXM1 | c.661C>A p.H221N | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DCLRE1A | c.3072G>C p.R1024S | Missense Mutation (SNP) | VAF 98/287 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- FAT3 | c.10015C>T p.P3339S | Missense Mutation (SNP) | VAF 123/361 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXE1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 204/738 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- GLB1L3 | c.1506C>A p.C502* | Nonsense Mutation (SNP) | VAF 53/157 reads (34%) | called by muse, mutect2, varscan2
- KRTAP5-5 | c.362C>A p.S121Y | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, varscan2
- MANSC4 | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 22/236 reads (9%) | called by mutect2, pindel
- PDS5A | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PLK2 | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 121/252 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- POLR2J2 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PSMA7 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- RTN2 | c.987C>A p.S329R | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNRC18 | c.3919A>C p.S1307R | Missense Mutation (SNP) | VAF 160/526 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR97 | c.3182_3183+1del | In Frame Del (DEL) | VAF 142/438 reads (32%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.8860C>A p.P2954T | Missense Mutation (SNP) | VAF 106/343 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.7836A>G p.K2612= | Silent (SNP) | VAF 110/407 reads (27%) | called by muse, mutect2, varscan2
- CIZ1 | c.2553C>T p.N851= | Silent (SNP) | VAF 161/466 reads (35%) | catalogued as rs376443811; called by muse, mutect2, varscan2
- CRISPLD1 | c.15G>A p.A5= | Silent (SNP) | VAF 69/223 reads (31%) | catalogued as rs766389465, COSV51547252; called by muse, mutect2, varscan2
- INTS13 | c.1653A>G p.Q551= | Silent (SNP) | VAF 107/357 reads (30%) | catalogued as rs1241935420, COSV53905103; called by muse, mutect2, varscan2
- PXDN | c.1803G>T p.G601= | Silent (SNP) | VAF 87/304 reads (29%) | called by muse, mutect2, varscan2
- SLC26A4 | c.1299C>T p.I433= | Silent (SNP) | VAF 87/275 reads (32%) | catalogued as rs397516415; ClinVar: likely benign; called by muse, mutect2, varscan2
- ST14 | c.201G>A p.L67= | Silent (SNP) | VAF 149/407 reads (37%) | called by muse, mutect2, varscan2
- TNC | c.1725C>T p.D575= | Silent (SNP) | VAF 115/380 reads (30%) | catalogued as rs774414409; called by muse, varscan2
- FGFR3 | c.*1387C>G | 3'UTR (SNP) | VAF 186/643 reads (29%) | called by muse, mutect2, varscan2
- TMEM107 | c.*667A>G | 3'UTR (SNP) | VAF 88/177 reads (50%) | catalogued as rs772145329; called by muse, mutect2, varscan2
